Somatic mutation profile of tumor specimen TCGA-WB-A81G-01A (aliquot TCGA-WB-A81G-01A-11D-A35I-08) from TCGA case TCGA-WB-A81G, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 25.3 years (9,248 days).
Specimen TCGA-WB-A81G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a4db8bd-933b-4cb7-b256-ada05eb0305a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81G-10A (Blood Derived Normal), aliquot TCGA-WB-A81G-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f860ee19-6e0d-4628-928b-72a00b45e68e

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 1, RNA 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHRR | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs764646609; called by muse, mutect2
- ANKRD44 | c.671A>G p.H224R | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs980498261; called by muse, mutect2
- FBLN2 | c.3254G>A p.R1085H | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1225439422, COSV55491486; called by muse, mutect2
- NFE2L2 | c.1684C>T p.L562F | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV101229346; called by muse, mutect2, varscan2
- SCNN1B | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.331); catalogued as rs1490458709; called by muse, mutect2
- ADGRL4 | c.876T>A p.N292K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- OSMR | c.1134+2_1134+5del p.X378_splice | Splice Site (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- ZNF185 | c.262C>A p.R88= | Splice Region (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- ZNF417 | c.1121A>G p.H374R | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAAP20 | c.210C>T p.C70= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- MIR216A | n.29T>A | RNA (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
